Surgical pathology report (de-identified scan), TCGA case TCGA-ZH-A8Y4, project TCGA-CHOL (Cholangiocarcinoma), tissue source site University of North Carolina, specimen TCGA-ZH-A8Y4-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

Cholangiocarcinoma
8160/3

Site: Intrahepatic bile duct 022.1

yo 11/3/14

Diagnosis:

A: Gallbladder and lymph nodes, removal

- No evidence of malignancy
- Three lymph nodes, negative for metastatic carcinoma (0/3)
(see comment)
- Chronic cholecystitis with cholelithiasis

B: Liver, segments, 4, 5 and 8, resection

- Moderate to poorly differentiated adenocarcinoma, most consistent with primary intrahepatic cholangiocarcinoma (see comment)
- Tumor size: 11.5 cm
- Tumor extent: tumor involves hepatic parenchyma
- Margins:
- Hepatic parenchymal margin: positive focally (B6)
- Portal vein margin: negative; tumor is 0.5 cm from portal vein margin
- No definitive lymphovascular space invasion identified
- No perineural invasion identified
- Nonneoplastic liver with macrovesicular steatosis involving approximately 10% of the hepatic parenchyma
- AJCC pathologic stage: pT1 pN0

Comment:

Sections of lymph nodes from specimen A show no evidence of metastatic carcinoma, confirmed by pan-cytokeratin stain.

Sections of the liver show a moderately differentiated adenocarcinoma within a desmoplastic background. The neoplastic cells exhibit moderate nuclear pleomorphism with easily identified mitotic figures. Immunohistochemical stains are performed and show the neoplastic cells to be focally positive for CK7 and negative for CK20, BerEP4, RCC, PSA, PSAP, TTF-1 and HepPAR1. These findings support the diagnosis of intrahepatic cholangiocarcinoma. Dr. has reviewed this case and agrees with the diagnosis.

A CD31 immunohistochemical stain is performed on block B4. No definitive lymphovascular space invasion is identified.

For cases in which immunostains are performed, the following applies:

Appropriate internal and/or external positive and negative

[page 2 of 3]
controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the

These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Clinical History:

-year-old male with cholangiocarcinoma.

Gross Description:

Specimen A is received in a formalin filled container labeled with the patient's name and as "gallbladder and lymph nodes".

Previously opened: no

Measurements: 8.5 x 3.0 x 1.0 cm

External surface: One surface exhibits a dusky pink-purple smooth glistening intact serosa. The opposite surface exhibits a roughened adhered surface consistent with contact with the hepatic surface. This surface exhibits a 1.2 cm gross dimension transmural defect. The hepatic surface is inked green.

Wall thickness: uniform 0.1 cm

Mucosa: The mucosal surface is dusky hemorrhagic red-brown with slight granularity.

Stones present: No gallstones are identified.

Other comments: Three cystic duct lymph node candidates are identified ranging in size from 0.8 cm up to 1.5 cm in greatest dimension. The cystic duct margin is inked blue, the hepatic surface is inked green.

Block #:

A1 cystic margin and representative sections of the gallbladder

A2 three cystic duct lymph node candidates

Specimen B received in a formalin filled container labeled with the patient's name and as "liver segment 4, 5, 8 resection" is a 400 g, 14.0 x 11.0 x 4.5 cm liver resectioned specimen. The resection margin is inked black, the portal vein margin is inked

[page 3 of 3]
red. The liver capsule is a dusky red-purple with patchy areas of tan-pink ulceration up to 1.0 cm in greatest dimension. The capsule has a central area which is tan-pink and lighter in color than the area surrounding it in the periphery which is a dusky purple-red. The capsule is centrally firm. Sectioning exhibits a 11.5 x 6.0 x 4.8 cm tan-white firm mass with ill defined irregular borders and patchy areas of hemorrhage. The mass grossly abuts the resection margin, is 0.3 cm from the capsule, and abuts the portal vein margin. The remainder of the liver parenchyma is a soft smooth glistening golden-yellow-orange. Ink: resection margin black, portal vein margin red.

Block Summary:

- B1 - tumor closest approach to resection margin
- B2 - tumor closest approach to portal vein margin
- B3-B4 - representative sections of the tumor and adjacent liver parenchyma and capsule
- B5 - uninvolved liver parenchyma
- B6 - additional section of tumor and parenchymal margin

Source: NCI Genomic Data Commons file 3a2fab18-676f-4069-9788-06589214f053 (TCGA-ZH-A8Y4.8C44AB5C-5F49-4F12-9273-F8AEDD9F0316.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).